FM case AD15078 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/43ce6dd7-704a-42ce-8592-6fe15a3f3249

Female, 57.0 years: Melanoma, NOS (ICD-O-3 8720/3) of the head, face or neck; specimen biopsied or resected from the mouth. Tumor nuclei on the sequenced sample's slide: 63% (pathologist estimate recorded by GDC). Sample type: Tumor.
